Somatic mutation profile of tumor specimen TARGET-30-PATTPW-01A (aliquot TARGET-30-PATTPW-01A-01D) from TARGET case TARGET-30-PATTPW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 7.6 years (2,790 days).
Specimen TARGET-30-PATTPW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12f57eb9-7b85-47a5-ba60-2c5d33d59fc5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATTPW-10A (Blood Derived Normal), aliquot TARGET-30-PATTPW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99761eee-77d2-48ee-b2f2-8d99999d66ef

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A3 | c.2908G>T p.E970* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV53409019; called by muse, mutect2
- DOCK3 | c.*915G>A | 3'UTR (SNP) | VAF 39/96 reads (41%) | catalogued as rs868936349, COSV56556360; called by muse, mutect2, varscan2
- KLHL3 | c.*2407G>T | 3'UTR (SNP) | VAF 31/129 reads (24%) | catalogued as COSV59059050; called by muse, mutect2, varscan2
